Somatic mutation profile of tumor specimen MMRF_2694_1_BM_CD138pos (aliquot MMRF_2694_1_BM_CD138pos_T1_KHS5U_L14843) from MMRF case MMRF_2694, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.8 years (22,202 days).
Specimen MMRF_2694_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46d99e50-811a-4daf-afd1-e00c9f873bb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2694_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2694_1_PB_WBC_C2_KHS5U_L14844; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4950b6d8-64a7-43e6-b2d1-d87f1933e2c3

The open-access MAF lists 173 somatic variants for this specimen: 61 protein-altering or splice-affecting, 31 silent, 81 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, 3'UTR 45, Silent 31, Intron 20, 5'UTR 5, 3'Flank 4, 5'Flank 4, Translation Start Site 3, RNA 3, Splice Site 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*194G>A | 3'UTR (SNP) | VAF 16/102 reads (16%) | catalogued as rs28931614, CM940785, CM940786, CX090489, COSV53399372, COSV99602429; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- FGFR3 | c.*1004A>G | 3'UTR (SNP) | VAF 41/187 reads (22%) | catalogued as rs78311289, CM002967, CM950476, COSV53390625, COSV53407424; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.3655dup p.I1219Nfs*22 | Frame Shift Ins (INS) | VAF 40/54 reads (74%) | catalogued as rs756859429; called by mutect2, varscan2
- C16orf78 | c.323G>C p.G108A | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.222); catalogued as COSV54559278; called by muse, mutect2, varscan2
- CCDC172 | c.513G>T p.L171F | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV60938215; called by muse, mutect2, varscan2
- CFAP65 | c.2458G>A p.V820I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as rs752204587, COSV100446081; called by muse, mutect2, varscan2
- CPA5 | c.198G>A p.K66= | Splice Region (SNP) | VAF 44/83 reads (53%) | catalogued as rs1470378617; called by muse, mutect2, varscan2
- DSG4 | c.2189C>T p.S730L | Missense Mutation (SNP) | VAF 109/227 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as rs1260703500, COSV57388088; called by muse, mutect2, varscan2
- GALNT18 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as rs372117986; called by muse, mutect2, varscan2
- HAUS8 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs145277823; called by muse, mutect2, varscan2
- IGHV2-70 | c.334G>C p.A112P | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs747324854; called by muse, varscan2
- IGHV2-70 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs534553794; called by muse, mutect2
- IGLV1-51 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.589); catalogued as rs760185782; called by muse, varscan2
- IGLV4-60 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs762327414; called by muse, mutect2, varscan2
- LRFN5 | c.708T>G p.S236R | Missense Mutation (SNP) | VAF 135/303 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53249808; called by muse, mutect2, varscan2
- MARCHF6 | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 110/235 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs774965742, COSV99929588; called by muse, mutect2, varscan2
- MAX | c.106A>G p.R36G | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52418001; called by muse, varscan2
- OTUD1 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs923351198; called by muse, mutect2, varscan2
- SI | c.409A>G p.T137A | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV52275254; called by muse, mutect2, varscan2
- SLC23A1 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.907); catalogued as COSV62297314; called by muse, mutect2, varscan2
- SYT16 | c.432G>C p.E144D | Missense Mutation (SNP) | VAF 61/75 reads (81%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV70857532; called by muse, mutect2, varscan2
- WDR64 | c.305A>T p.D102V | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.893); catalogued as rs1231314485; called by muse, mutect2
- WSCD2 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1248846599, COSV99775343; called by muse, mutect2, varscan2
- ZNF578 | c.5T>C p.L2S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as rs778021467; called by muse, mutect2, varscan2
- ACAD10 | c.14G>T p.S5I | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADAMTSL1 | c.3424A>T p.S1142C | Missense Mutation (SNP) | VAF 93/106 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- CDC42BPB | c.1484A>C p.E495A | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CHMP2B | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- COL18A1 | c.2196T>A p.D732E (on ENST00000359759 / NM_130444.3; = p.D497E on NM_030582.4) | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCTN1 | c.2242G>A p.D748N | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DENND2B | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 107/277 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- DIS3 | c.1523A>C p.D508A | Missense Mutation (SNP) | VAF 40/44 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSE | c.2491G>A p.V831I | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- DYNC1I2 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); called by muse, mutect2
- HIPK3 | c.1180C>T p.L394F | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNF1A | c.1471G>C p.A491P | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- IGFBP6 | c.583T>C p.F195L | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IGLV1-51 | c.265_270dup p.T89_S90dup | In Frame Ins (INS) | VAF 10/66 reads (15%) | called by muse*, pindel, varscan2
- KCNQ2 | c.1960G>A p.E654K (on ENST00000359125 / NM_172107.4; = p.E626K on NM_004518.6) | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRTAP6-1 | c.214T>G p.*72Gext*12 | Nonstop Mutation (SNP) | VAF 110/232 reads (47%) | called by muse, mutect2, varscan2
- LAT | c.782T>A p.L261Q | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP1B | c.1491A>T p.K497N | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MATR3 | c.844C>A p.H282N | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- MAX | c.85A>T p.N29Y | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MROH1 | c.3634G>C p.A1212P | Missense Mutation (SNP) | VAF 27/29 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NCOR1 | c.1925A>T p.E642V | Missense Mutation (SNP) | VAF 74/268 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, varscan2
- NLGN2 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NYX | c.533T>A p.L178Q | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- PAPPA2 | c.2875C>T p.H959Y | Missense Mutation (SNP) | VAF 126/209 reads (60%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, varscan2
- PIK3C2B | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PPM1L | c.897G>T p.L299F | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PRADC1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); called by muse, mutect2
- RNF216 | c.1286G>A p.R429K (on ENST00000425013 / NM_207116.3; = p.R486K on NM_207111.4) | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SESN3 | c.1064C>A p.T355N | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- SPOCK3 | c.1140T>G p.C380W | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STK16 | c.309_310del p.X103_splice | Splice Site (DEL) | VAF 52/132 reads (39%) | called by pindel, varscan2
- TPCN2 | c.1682G>T p.S561I | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2
- TRPM5 | c.1259G>T p.R420L | Missense Mutation (SNP) | VAF 110/223 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TTC7A | c.1988C>A p.T663N | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- VCPIP1 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 17/46 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- WSCD2 | c.1419G>C p.K473N | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- XPO7 | c.343A>T p.I115F | Missense Mutation (SNP) | VAF 99/270 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ZNF783 | c.777A>T p.R259S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- AAK1 | c.2829C>T p.S943= | Silent (SNP) | VAF 26/169 reads (15%) | called by muse, mutect2, varscan2
- ACY3 | c.450G>A p.L150= | Silent (SNP) | VAF 40/128 reads (31%) | called by muse, mutect2, varscan2
- APC2 | c.2022T>C p.N674= | Silent (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- ARID1A | c.5181C>A p.I1727= | Silent (SNP) | VAF 46/94 reads (49%) | called by muse, mutect2, varscan2
- CCDC8 | c.1416G>C p.R472= | Silent (SNP) | VAF 100/194 reads (52%) | catalogued as COSV100281813; called by muse, mutect2, varscan2
- CD101 | c.912C>T p.C304= | Silent (SNP) | VAF 56/133 reads (42%) | catalogued as COSV99869962; called by muse, mutect2, varscan2
- CEP152 | c.2913C>A p.I971= | Silent (SNP) | VAF 101/218 reads (46%) | catalogued as COSV57857306; called by muse, mutect2, varscan2
- CLASP1 | c.531A>G p.G177= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as rs1230115544; called by muse, mutect2, varscan2
- COL18A1 | c.276C>T p.D92= | Silent (SNP) | VAF 142/296 reads (48%) | called by muse, mutect2, varscan2
- DNAH9 | c.13041A>T p.T4347= | Silent (SNP) | VAF 66/146 reads (45%) | called by muse, mutect2, varscan2
- ENTPD2 | c.483G>A p.S161= | Silent (SNP) | VAF 38/177 reads (21%) | catalogued as rs1285879375; called by muse, mutect2, varscan2
- FAM110C | c.654C>T p.F218= | Silent (SNP) | VAF 71/160 reads (44%) | called by muse, mutect2, varscan2
- FAM53A | c.682C>A p.R228= | Silent (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- GCNT1 | c.258T>C p.P86= | Silent (SNP) | VAF 21/194 reads (11%) | catalogued as rs1370914858; called by muse, mutect2, varscan2
- IFT122 | c.3003C>T p.T1001= (on ENST00000348417 / NM_052989.3; = p.T942= on NM_018262.4) | Silent (SNP) | VAF 72/148 reads (49%) | catalogued as rs757583043, COSV99959430; called by muse, mutect2, varscan2
- IGHV1-69D | c.294C>T p.A98= | Silent (SNP) | VAF 110/131 reads (84%) | catalogued as rs1188707005; called by muse, mutect2, varscan2
- IGHV1-69D | c.66G>A p.Q22= | Silent (SNP) | VAF 14/18 reads (78%) | called by mutect2, varscan2
- IL18RAP | c.1233C>T p.F411= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as rs140183707; called by muse, mutect2, varscan2
- IL20RB | c.540C>T p.V180= | Silent (SNP) | VAF 55/141 reads (39%) | catalogued as COSV59047294; called by muse, mutect2, varscan2
- IPP | c.600C>T p.V200= | Silent (SNP) | VAF 130/255 reads (51%) | called by muse, mutect2, varscan2
- KCNK16 | c.411G>A p.V137= | Silent (SNP) | VAF 43/88 reads (49%) | catalogued as COSV100949084; called by muse, mutect2, varscan2
- KIF26B | c.2466C>T p.G822= | Silent (SNP) | VAF 201/316 reads (64%) | catalogued as rs1374799182; called by muse, mutect2, varscan2
- LSG1 | c.1332A>G p.P444= | Silent (SNP) | VAF 33/137 reads (24%) | called by muse, mutect2, varscan2
- OR6K2 | c.327T>C p.C109= | Silent (SNP) | VAF 34/213 reads (16%) | called by muse, mutect2, varscan2
- PCDH11X | c.1560C>T p.G520= | Silent (SNP) | VAF 161/165 reads (98%) | called by muse, mutect2, varscan2
- PLA2G4A | c.384T>A p.T128= | Silent (SNP) | VAF 19/102 reads (19%) | called by muse, mutect2, varscan2
- PNN | c.1062G>A p.E354= | Silent (SNP) | VAF 65/138 reads (47%) | called by muse, mutect2, varscan2
- POU3F2 | c.222T>C p.G74= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as rs1280489469; called by muse, mutect2, varscan2
- PPM1H | c.225C>T p.P75= | Silent (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- RTL1 | c.3051G>A p.L1017= | Silent (SNP) | VAF 91/202 reads (45%) | called by muse, mutect2, varscan2
- TOR1B | c.12T>G p.A4= | Silent (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- ADAP2 | chr17:30921854 G>A | 5'Flank (SNP) | VAF 22/32 reads (69%) | catalogued as rs990632613; called by muse, mutect2, varscan2
- AFF4 | c.*2953C>G | 3'UTR (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- ANAPC4 | c.1061+19A>T | Intron (SNP) | VAF 31/159 reads (19%) | called by muse, mutect2, varscan2
- ANKRD33 | c.263-45C>T | Intron (SNP) | VAF 140/333 reads (42%) | catalogued as rs991612412; called by muse, mutect2, varscan2
- ANP32E | c.*1339G>A | 3'UTR (SNP) | VAF 49/176 reads (28%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.*4163T>C | 3'UTR (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- ATOH1 | c.*14G>A | 3'UTR (SNP) | VAF 51/310 reads (16%) | called by muse, mutect2, varscan2
- ATP11AUN | n.1066T>A | RNA (SNP) | VAF 91/99 reads (92%) | called by muse, mutect2, varscan2
- ATP2A3 | c.*16C>T | 3'UTR (SNP) | VAF 50/99 reads (51%) | catalogued as rs376607630; called by muse, mutect2, varscan2
- BTN2A2 | c.*1530T>A | 3'UTR (SNP) | VAF 46/105 reads (44%) | called by muse, mutect2, varscan2
- BZW2 | c.*172G>A | 3'UTR (SNP) | VAF 54/96 reads (56%) | called by muse, mutect2, varscan2
- C1QTNF2 | c.*67A>G | 3'UTR (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- CCDC186 | c.*1830T>G | 3'UTR (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- CCDC85A | c.-143G>A | 5'UTR (SNP) | VAF 16/25 reads (64%) | called by muse, mutect2, varscan2
- CCDC92 | c.35-208G>A | Intron (SNP) | VAF 40/86 reads (47%) | called by muse, mutect2, varscan2
- CLIP1 | c.*371del | 3'UTR (DEL) | VAF 24/73 reads (33%) | called by mutect2, pindel, varscan2
- CMTR2 | c.*955T>G | 3'UTR (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- CNOT2 | c.48+47A>T | Intron (SNP) | VAF 44/92 reads (48%) | called by muse, mutect2, varscan2
- CNPY3 | c.-86C>A | 5'UTR (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- COBL | c.1096+13322T>C | Intron (SNP) | VAF 35/99 reads (35%) | called by muse, mutect2, varscan2
- CRACR2A | c.1271+1209T>C | Intron (SNP) | VAF 12/50 reads (24%) | catalogued as rs944150617; called by muse, mutect2, varscan2
- CWC22 | c.*170T>C | 3'UTR (SNP) | VAF 22/39 reads (56%) | called by muse, mutect2, varscan2
- DDI1 | c.*150C>T | 3'UTR (SNP) | VAF 55/114 reads (48%) | called by muse, mutect2, varscan2
- DNAJA2 | c.*1380C>T | 3'UTR (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- DPY19L2P2 | n.3250C>T | RNA (SNP) | VAF 12/39 reads (31%) | catalogued as rs769820970; called by muse, mutect2, varscan2
- DSEL | c.*1197A>G | 3'UTR (SNP) | VAF 44/96 reads (46%) | called by muse, mutect2, varscan2
- EBF3 | c.1759+1043G>A | Intron (SNP) | VAF 50/109 reads (46%) | called by muse, mutect2, varscan2
- FAM204A | chr10:118307830 A>T | 3'Flank (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- FAM210A | c.*1672T>A | 3'UTR (SNP) | VAF 38/96 reads (40%) | called by muse, mutect2, varscan2
- FCER2 | c.316+76C>G | Intron (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- FCGR3B | c.*725A>C | 3'UTR (SNP) | VAF 66/272 reads (24%) | called by muse, mutect2, varscan2
- FGF20 | c.*757T>A | 3'UTR (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- FNIP2 | c.*2865A>G | 3'UTR (SNP) | VAF 39/98 reads (40%) | called by muse, mutect2, varscan2
- HNRNPH1 | c.398-46T>C | Intron (SNP) | VAF 80/167 reads (48%) | called by muse, mutect2, varscan2
- IFIT5 | c.*366T>A | 3'UTR (SNP) | VAF 39/73 reads (53%) | called by muse, mutect2, varscan2
- ITSN1 | c.*10090G>A | 3'UTR (SNP) | VAF 25/121 reads (21%) | called by muse, mutect2, varscan2
- KCNB1 | c.*527C>T | 3'UTR (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- KDM4E | c.-149G>C | 5'UTR (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- LAMB1 | c.3947-58T>A | Intron (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- LMNB2 | c.*1210_*1213del | 3'UTR (DEL) | VAF 32/144 reads (22%) | called by mutect2, pindel, varscan2
- LMO3 | c.*542dup | 3'UTR (INS) | VAF 14/75 reads (19%) | called by mutect2, pindel, varscan2
- LRATD1 | c.*1995T>G | 3'UTR (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- LRRC3 | c.*109C>T | 3'UTR (SNP) | VAF 36/83 reads (43%) | called by muse, mutect2, varscan2
- MFSD8 | c.-75-50T>C | Intron (SNP) | VAF 25/101 reads (25%) | catalogued as rs986042603; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851399 T>C | 5'Flank (SNP) | VAF 113/207 reads (55%) | catalogued as rs1463860034; called by muse, mutect2, varscan2
- MLANA | chr9:5910662 C>T | 3'Flank (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
- MUC6 | c.*516C>A | 3'UTR (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- MYEF2 | c.*1680G>A | 3'UTR (SNP) | VAF 118/293 reads (40%) | catalogued as COSV99981958; called by muse, mutect2, varscan2
- NREP | c.*291C>T | 3'UTR (SNP) | VAF 31/165 reads (19%) | catalogued as rs1022041543; called by muse, mutect2, varscan2
- NUDT13 | c.*623A>G | 3'UTR (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- OGFOD1 | chr16:56451531 A>G | 5'Flank (SNP) | VAF 103/194 reads (53%) | catalogued as rs111983939; called by mutect2, varscan2
- OPRL1 | c.*285C>G | 3'UTR (SNP) | VAF 25/112 reads (22%) | catalogued as rs538616735; called by muse, mutect2, varscan2
- OR4H12P | n.2T>C | RNA (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- P4HA1 | c.*766A>T | 3'UTR (SNP) | VAF 37/77 reads (48%) | called by muse, mutect2, varscan2
- PARP16 | c.-51G>A | 5'UTR (SNP) | VAF 20/51 reads (39%) | catalogued as rs1339861838; called by muse, mutect2, varscan2
- PHC2 | c.1759-18G>A | Intron (SNP) | VAF 27/134 reads (20%) | catalogued as rs1303459787; called by muse, mutect2, varscan2
- PPFIA4 | c.2782-10T>C | Intron (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- PPP1CB | c.*1664T>A | 3'UTR (SNP) | VAF 74/149 reads (50%) | called by muse, mutect2, varscan2
- PSMD12 | c.*1852A>C | 3'UTR (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- PXMP4 | c.*93C>T | 3'UTR (SNP) | VAF 47/87 reads (54%) | catalogued as COSV54134539; called by muse, mutect2, varscan2
- RAB17 | c.436-42T>C | Intron (SNP) | VAF 19/42 reads (45%) | catalogued as rs1163081348; called by muse, mutect2, varscan2
- RBFOX1 | c.414+166291G>A | Intron (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- RNF125 | c.*366C>G | 3'UTR (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- RNF167 | chr17:4940024 A>C | 5'Flank (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- ROPN1B | c.116+294T>C | Intron (SNP) | VAF 110/243 reads (45%) | called by muse, mutect2, varscan2
- S1PR2 | c.-43+784C>G | Intron (SNP) | VAF 26/82 reads (32%) | catalogued as rs538224926, COSV73912640, COSV73912837; called by muse, varscan2
- SNTN | c.*2359C>A | 3'UTR (SNP) | VAF 56/201 reads (28%) | called by muse, mutect2, varscan2
- SNX24 | c.*702G>C | 3'UTR (SNP) | VAF 54/99 reads (55%) | called by muse, mutect2, varscan2
- SYPL2 | c.*83C>G | 3'UTR (SNP) | VAF 26/105 reads (25%) | catalogued as rs1033077354; called by muse, mutect2, varscan2
- TECRL | chr4:64275567 T>G | 3'Flank (SNP) | VAF 59/125 reads (47%) | called by muse, mutect2, varscan2
- TLX3 | c.*55C>G | 3'UTR (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- TNFAIP3 | c.*924T>A | 3'UTR (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- TRIQK | chr8:92883941 T>C | 3'Flank (SNP) | VAF 47/49 reads (96%) | called by muse, mutect2, varscan2
- TRMT1L | c.-193T>C | 5'UTR (SNP) | VAF 60/218 reads (28%) | called by muse, mutect2, varscan2
- TTC39A | c.1161+1902G>A | Intron (SNP) | VAF 38/61 reads (62%) | called by muse, mutect2, varscan2
- YWHAH | c.87+757T>A | Intron (SNP) | VAF 28/114 reads (25%) | called by muse, mutect2, varscan2
- ZFAND6 | c.*57T>A | 3'UTR (SNP) | VAF 34/236 reads (14%) | called by mutect2, varscan2
- ZNF783 | c.803-4352C>T | Intron (SNP) | VAF 8/24 reads (33%) | catalogued as rs768972770; called by muse, mutect2, varscan2
- ZNF827 | c.*667C>T | 3'UTR (SNP) | VAF 28/223 reads (13%) | catalogued as rs1041877971; called by muse, mutect2, varscan2
